Somatic mutation profile of tumor specimen MP2PRT-PAUEVU-TMP1-A (aliquot MP2PRT-PAUEVU-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUEVU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,158 days).
Specimen MP2PRT-PAUEVU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92546151-5692-4dc8-88a9-c2c8d34c1150.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEVU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEVU-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8bc274a-a69c-44a1-ab88-4f5dda3e8449

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1B | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 104/218 reads (48%) | catalogued as rs1568670481, CM042491; ClinVar: pathogenic; called by muse, varscan2
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- BEND4 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370327170, COSV72469475; called by muse, mutect2
- GREB1 | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs147686450; called by muse, mutect2, varscan2
- HSPA1L | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 183/455 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs1461660496; called by muse, mutect2, varscan2
- PCDHB7 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 119/333 reads (36%) | catalogued as rs566132808, COSV50804900; called by muse, mutect2, varscan2
- SYN2 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1559451493; called by muse, mutect2, varscan2
- ADAM28 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- BCL11A | c.1469_1472delinsTATTTC p.H490Lfs*75 (on ENST00000335712 / NM_001365609.1; = p.H524Lfs*75 on NM_018014.4) | Frame Shift Ins (INS) | VAF 92/731 reads (13%) | called by pindel, varscan2*
- CD163L1 | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 154/406 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.11290T>A p.L3764M | Missense Mutation (SNP) | VAF 110/355 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCHSD1 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAPKBP1 | c.1726G>T p.A576S (on ENST00000456763 / NM_001128608.2; = p.A570S on NM_014994.3) | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NCBP3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 167/431 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFKBIZ | c.1151C>G p.A384G | Missense Mutation (SNP) | VAF 85/483 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHA7 | c.1125T>G p.F375L | Missense Mutation (SNP) | VAF 88/324 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLC5A8 | c.1796C>A p.S599* | Nonsense Mutation (SNP) | VAF 32/416 reads (8%) | called by muse, mutect2
- APBA1 | c.648C>T p.Y216= | Silent (SNP) | VAF 75/553 reads (14%) | catalogued as rs1199394322; called by muse, mutect2, varscan2
- GRIA2 | c.2622C>T p.N874= | Silent (SNP) | VAF 33/139 reads (24%) | catalogued as rs747357354, COSV52386476, COSV99644602; called by muse, mutect2, varscan2
- MPP1 | c.18C>T p.S6= | Silent (SNP) | VAF 141/586 reads (24%) | catalogued as COSV65728273; called by muse, mutect2, varscan2
